TCGA case TCGA-CV-7252 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/24ecbe19-a9ea-4215-a7f1-74300f9ed2a9

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 62 years; Vital status: Dead; Days to death: 151 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 62.8 years (22,934 days); Year of diagnosis: 1994; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 34; Lymphatic invasion present: No; Margin status: Involved; Perineural invasion present: Yes; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Modified Radical Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 33 days; Days to treatment end: 89 days; Treatment dose: 63 Gy; Treatment outcome: Progressive Disease; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Cure; Days to treatment end: 89 days; Treatment outcome: Persistent Disease.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 151 days; Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-7252-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.6; Shortest dimension: 0.5.
  Slide TCGA-CV-7252-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-CV-7252-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 40.
- Sample TCGA-CV-7252-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-7252-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-CV-7252-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.5; Intermediate dimension: 1.1; Shortest dimension: 0.9.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Cavity; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Positive; Lymphovascular invasion: No; Tobacco smoking history indicator: 1; Alcohol history documented: No.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Definitive treatment method: Radiation; Definitive treatment evidence disease after: Yes; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 151 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 151 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 151 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CV-7252-01A-11D-2010-01): tumor purity 0.47, ploidy 1.91, whole-genome doublings 0.
